Somatic mutation profile of tumor specimen TCGA-AR-A0TT-01A (aliquot TCGA-AR-A0TT-01A-31D-A099-09) from TCGA case TCGA-AR-A0TT, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 53.9 years (19,679 days).
Specimen TCGA-AR-A0TT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d1aa771-f556-40f5-9039-320b5bf32e66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A0TT-10A (Blood Derived Normal), aliquot TCGA-AR-A0TT-10A-01D-A099-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/daa3c9e2-1acb-40e5-a853-acae17485ac4

The open-access MAF lists 60 somatic variants for this specimen: 46 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 38, Silent 14, Frame Shift Del 3, Splice Site 3, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.11693C>T p.T3898I | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as COSV71290601; called by muse, mutect2, varscan2
- ACKR1 | c.827G>T p.C276F | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100929548; called by muse, mutect2, varscan2
- ADGRG4 | c.7322A>T p.K2441M | Missense Mutation (SNP) | VAF 55/235 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as COSV99795338; called by muse, mutect2, varscan2
- AMIGO1 | c.1030A>G p.M344V | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100881049; called by muse, mutect2, varscan2
- ARHGAP21 | c.2341G>T p.V781F | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV100256102, COSV100256129; called by muse, mutect2, varscan2
- ATPSCKMT | c.677A>G p.H226R | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV99725839; called by muse, mutect2, varscan2
- BNC2 | c.2918G>A p.S973N | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV101035935; called by muse, mutect2, varscan2
- CENPJ | c.429T>A p.F143L | Missense Mutation (SNP) | VAF 27/278 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0.048); catalogued as COSV101121506; called by muse, mutect2
- DDX60L | c.614C>G p.T205R | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99487549; called by muse, mutect2, varscan2
- EMC10 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as rs369893864; called by muse, mutect2, varscan2
- EXOC1 | c.2147T>G p.V716G | Missense Mutation (SNP) | VAF 47/320 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.544); catalogued as COSV100637850; called by muse, mutect2, varscan2
- GALNS | c.1528C>A p.P510T | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.03); catalogued as COSV51937677; called by muse, mutect2, varscan2
- GRID2 | c.2193G>T p.K731N | Missense Mutation (SNP) | VAF 7/176 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV56237496; called by muse, mutect2
- GUCA1A | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV50003456; called by muse, mutect2, varscan2
- LRRK1 | c.2217G>C p.W739C | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52602416, COSV99439562; called by muse, mutect2
- LRTM1 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as COSV99836017; called by muse, mutect2, varscan2
- ME2 | c.985G>C p.E329Q | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.045); catalogued as COSV100360761; called by muse, mutect2, varscan2
- MSLN | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.619); catalogued as rs966765258, COSV67021735; called by muse, mutect2
- N4BP1 | c.1184G>C p.R395T | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99285111; called by muse, mutect2, varscan2
- N4BP1 | c.855G>C p.R285S | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99285114; called by muse, mutect2
- NCOR1 | c.435+2T>C p.X145_splice | Splice Site (SNP) | VAF 15/55 reads (27%) | catalogued as COSV51976690; called by muse, mutect2, varscan2
- NPAS3 | c.1046+2T>C p.X349_splice (on ENST00000356141 / NM_001164749.2; = p.X317_splice on NM_022123.3) | Splice Site (SNP) | VAF 22/79 reads (28%) | catalogued as COSV100640192, COSV60842005; called by muse, mutect2, varscan2
- NT5DC2 | c.1299G>A p.L433= | Splice Region (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100194876, COSV58736920; called by muse, mutect2
- OR2A42 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as rs764203936, COSV66955789; called by mutect2, varscan2
- PCDHGA2 | c.1937T>A p.I646N | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as COSV99537186; called by muse, mutect2, varscan2
- PDE6A | c.1836G>C p.M612I | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.481); catalogued as COSV99678253; called by muse, mutect2, varscan2
- PER1 | c.1478T>C p.I493T | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100424509; called by muse, mutect2, varscan2
- PKP4 | c.2032G>A p.D678N | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV100733825; called by muse, mutect2, varscan2
- PLXNA3 | c.3763C>A p.R1255S | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV63753741; called by muse, mutect2, varscan2
- RORC | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV100561914; called by muse, mutect2, varscan2
- RYR2 | c.12253A>C p.K4085Q | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV100769868; called by muse, mutect2, varscan2
- SFRP1 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV55173142; called by muse, mutect2, varscan2
- SH3GL3 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 17/342 reads (5%) | catalogued as COSV61054324; called by muse, mutect2
- SLC12A7 | c.1145C>T p.T382M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs141825245; called by muse, mutect2
- SMG8 | c.1844G>A p.R615K | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV99958810; called by muse, mutect2, varscan2
- SMG8 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 15/163 reads (9%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.989); catalogued as COSV99958811; called by muse, mutect2
- SRSF4 | c.460A>G p.K154E | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.549); catalogued as COSV100861390; called by muse, mutect2, varscan2
- TBC1D8B | c.854A>T p.E285V | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV99344318; called by muse, mutect2, varscan2
- TRIM49 | c.412-2A>T p.X138_splice | Splice Site (SNP) | VAF 16/154 reads (10%) | catalogued as COSV100316031; called by muse, mutect2
- TRIM63 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV100958149; called by muse, mutect2, varscan2
- VCP | c.1675G>A p.V559I | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.863); catalogued as COSV100734190; called by muse, mutect2
- WNT11 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 48/77 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1218682764, COSV59443089; called by muse, mutect2, varscan2
- FOXO3 | c.1873G>C p.E625Q | Missense Mutation (SNP) | VAF 18/593 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); called by muse, mutect2
- KCNB2 | c.2540_2548delinsGT p.E847Gfs*23 | Frame Shift Del (DEL) | VAF 29/122 reads (24%) | called by pindel, varscan2*
- NBEA | c.3673_3674del p.L1225Sfs*5 | Frame Shift Del (DEL) | VAF 51/176 reads (29%) | called by mutect2, pindel, varscan2
- SLC35F2 | c.1062del p.I355Lfs*6 | Frame Shift Del (DEL) | VAF 11/93 reads (12%) | called by mutect2, pindel, varscan2
- CDKL5 | c.1869G>A p.K623= | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as COSV101184288, COSV66113055; called by muse, mutect2
- CFH | c.1260C>T p.Y420= | Silent (SNP) | VAF 20/216 reads (9%) | catalogued as rs377222601, COSV100661424, COSV62778324; called by muse, mutect2
- HMCN1 | c.4653A>T p.G1551= | Silent (SNP) | VAF 18/234 reads (8%) | catalogued as COSV99628583; called by muse, mutect2
- KPNA1 | c.1326T>A p.V442= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV100724190; called by muse, mutect2, varscan2
- MRPL54 | c.159C>T p.S53= | Silent (SNP) | VAF 41/155 reads (26%) | catalogued as rs750591489, COSV100349655; called by muse, mutect2, varscan2
- NIPAL4 | c.819C>T p.L273= | Silent (SNP) | VAF 57/177 reads (32%) | catalogued as COSV99977023; called by muse, mutect2, varscan2
- NLRP13 | c.1329C>T p.Y443= | Silent (SNP) | VAF 30/135 reads (22%) | catalogued as rs768162534, COSV61619711, COSV61622587; called by muse, mutect2, varscan2
- NOTCH4 | c.300C>T p.S100= | Silent (SNP) | VAF 16/140 reads (11%) | catalogued as COSV100900645; called by muse, mutect2
- OR2G3 | c.297G>A p.A99= | Silent (SNP) | VAF 40/155 reads (26%) | catalogued as rs145338640, COSV60682358, COSV60682510; called by muse, mutect2, varscan2
- PCDHA10 | c.1371C>T p.S457= | Silent (SNP) | VAF 22/99 reads (22%) | catalogued as rs1212055845, COSV56474795; called by muse, mutect2, varscan2
- RPS6KC1 | c.906T>C p.S302= | Silent (SNP) | VAF 14/232 reads (6%) | catalogued as COSV100873796; called by muse, mutect2
- SWT1 | c.2484C>G p.L828= | Silent (SNP) | VAF 18/309 reads (6%) | catalogued as COSV100833264; called by muse, mutect2
- TIMP2 | c.615C>T p.R205= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs200738772, COSV99430396; called by muse, mutect2, varscan2
- WASHC5 | c.1449A>C p.I483= | Silent (SNP) | VAF 22/125 reads (18%) | catalogued as COSV100572816; called by muse, mutect2, varscan2
